Somatic mutation profile of tumor specimen TCGA-77-7140-01A (aliquot TCGA-77-7140-01A-41D-2042-08) from TCGA case TCGA-77-7140, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.3 years (25,303 days).
Specimen TCGA-77-7140-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44d2f40e-fa1a-4cb3-9e22-7152a568ed30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-7140-10A (Blood Derived Normal), aliquot TCGA-77-7140-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87ea21b3-15f8-4f1d-b9cf-379473458795

The open-access MAF lists 203 somatic variants for this specimen: 151 protein-altering or splice-affecting, 45 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 45, Frame Shift Del 8, Splice Site 7, Nonsense Mutation 4, Intron 3, In Frame Del 2, 3'UTR 2, RNA 2, Translation Start Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 48/58 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACTG2 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV100609547; called by muse, mutect2, varscan2
- ADAMTSL2 | c.681T>A p.L227= | Splice Region (SNP) | VAF 35/38 reads (92%) | catalogued as COSV100619063; called by muse, mutect2, varscan2
- ADCY5 | c.2456del p.P819Hfs*14 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as COSV100568020; called by mutect2, pindel
- AGAP1 | c.2048A>G p.E683G (on ENST00000304032 / NM_001037131.3; = p.E630G on NM_014914.5) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.912); catalogued as COSV100367215; called by muse, mutect2, varscan2
- ALB | c.1070A>C p.E357A | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV99892399; called by muse, mutect2, varscan2
- ANKRD53 | c.585C>G p.Y195* | Nonsense Mutation (SNP) | VAF 52/86 reads (60%) | catalogued as COSV99721602; called by muse, mutect2, varscan2
- API5 | c.1279-2A>G p.X427_splice | Splice Site (SNP) | VAF 19/88 reads (22%) | catalogued as COSV101124617, COSV66634850; called by muse, mutect2, varscan2
- APMAP | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.173); catalogued as COSV99469146; called by muse, mutect2, varscan2
- ARAP2 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.956); catalogued as COSV100394605, COSV58287024; called by muse, mutect2, varscan2
- ATM | c.8272G>C p.V2758L | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV99592229; called by muse, mutect2, varscan2
- ATP10A | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100791597; called by muse, mutect2, varscan2
- ATP13A2 | c.2187G>T p.K729N | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100454500; called by muse, mutect2, varscan2
- C10orf90 | c.1772T>G p.L591R | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777039140, COSV99505291; called by muse, mutect2, varscan2
- C10orf90 | c.896A>T p.H299L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV99505294; called by muse, mutect2, varscan2
- C3orf70 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV100621362; called by muse, mutect2, varscan2
- CACNA1E | c.6868G>C p.G2290R (on ENST00000367573 / NM_001205293.3; = p.G2247R on NM_000721.4) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV100705595; called by muse, mutect2, varscan2
- CASP5 | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV99508152; called by muse, mutect2, varscan2
- CAVIN4 | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766006712, COSV100293427, COSV56868331; called by muse, mutect2, varscan2
- CD47 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62528708; called by muse, mutect2, varscan2
- CEP164 | c.3058G>T p.A1020S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.164); catalogued as COSV99634525; called by muse, mutect2, varscan2
- CHD4 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 305/454 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as rs959477683, COSV58910498; called by muse, mutect2, varscan2
- CHRD | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 200/463 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); catalogued as COSV99200871; called by muse, mutect2, varscan2
- CHRDL1 | c.1166C>G p.S389C (on ENST00000372045; = p.S395C on NM_145234.4) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV99488767; called by muse, mutect2, varscan2
- COL4A3 | c.4840C>G p.L1614V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV101170577, COSV67417069; called by muse, mutect2, varscan2
- CPED1 | c.2632A>T p.R878W | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100121593; called by muse, mutect2, varscan2
- CRNN | c.1241G>T p.R414M | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV99664443; called by muse, mutect2, varscan2
- CSMD3 | c.7142G>T p.G2381V (on ENST00000297405 / NM_001363185.1; = p.G2277V on NM_052900.3) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52199034, COSV99820898; called by muse, mutect2, varscan2
- CUBN | c.4877C>A p.T1626N | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100913649; called by muse, mutect2, varscan2
- DCX | c.812G>T p.C271F | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV100576790; called by muse, mutect2, varscan2
- DDX60L | c.2402T>A p.V801D | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99488586; called by muse, mutect2, varscan2
- DENND4C | c.4900T>A p.F1634I (on ENST00000434457 / NM_001330640.2; = p.F1585I on NM_017925.7) | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.323); catalogued as COSV100727621; called by muse, mutect2, varscan2
- DNAH10 | c.9008C>A p.T3003N (on ENST00000409039; = p.T2942N on NM_207437.3) | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV101292866; called by muse, mutect2, varscan2
- DNAJC1 | c.999G>C p.E333D | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV100981439; called by muse, mutect2, varscan2
- DNASE2B | c.455C>A p.P152Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101042146, COSV65737205; called by muse, mutect2
- DNMT1 | c.2392T>C p.C798R | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV100533139; called by muse, mutect2, varscan2
- DPY19L3 | c.328G>C p.G110R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100639319; called by muse, mutect2, varscan2
- DST | c.4569A>C p.E1523D (on ENST00000361203 / NM_001374722.1; = p.E1197D on NM_015548.5) | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs1272644325, COSV99760428; called by muse, mutect2, varscan2
- EFNB3 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.449); catalogued as COSV99873027; called by muse, mutect2, varscan2
- EIF3D | c.1193A>C p.E398A | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99341789; called by muse, mutect2, varscan2
- EIF3G | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV99462989; called by muse, mutect2
- ENO3 | c.7A>T p.M3L | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV99850730; called by muse, mutect2, varscan2
- ERBB4 | c.2200A>T p.K734* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99634449; called by muse, mutect2, varscan2
- ESPNL | c.1512G>C p.E504D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100547961; called by muse, varscan2
- FABP7 | c.209A>T p.E70V | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100738018; called by muse, mutect2, varscan2
- FAM117B | c.890G>T p.S297I | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100288016; called by muse, mutect2, varscan2
- FGD1 | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.675); catalogued as COSV100911273; called by muse, mutect2
- FLT1 | c.1551+2T>C p.X517_splice | Splice Site (SNP) | VAF 33/40 reads (83%) | catalogued as COSV99167771; called by muse, mutect2, varscan2
- FN1 | c.5746C>G p.P1916A | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.166); catalogued as COSV100118447; called by mutect2, varscan2
- FOXA2 | c.1280T>C p.V427A (on ENST00000377115 / NM_153675.3; = p.V433A on NM_021784.5) | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.457); catalogued as COSV101008530; called by muse, mutect2, varscan2
- FRRS1 | c.1597-1G>T p.X533_splice | Splice Site (SNP) | VAF 24/43 reads (56%) | catalogued as COSV99790282; called by muse, mutect2, varscan2
- GART | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 90/114 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100738290; called by muse, mutect2, varscan2
- GGCX | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52087569; called by muse, mutect2
- GP5 | c.1617C>G p.I539M | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100541047, COSV59878710; called by muse, mutect2, varscan2
- GRK7 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767011044, COSV99380342; called by muse, mutect2, varscan2
- GRM1 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs1018703074, COSV51148350, COSV51189456; called by muse, mutect2, varscan2
- GTF3C1 | c.3769C>T p.R1257W | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1343037707, COSV100649774; called by muse, mutect2, varscan2
- H2BC8 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.884); catalogued as COSV99773428; called by muse, mutect2, varscan2
- HAUS1 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs773152415, COSV56363770, COSV99959602; called by muse, mutect2, varscan2
- HEYL | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100865348; called by muse, mutect2, varscan2
- HIF3A | c.1652G>A p.C551Y (on ENST00000377670 / NM_152795.4; = p.C482Y on NM_022462.4) | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.154); catalogued as COSV52198013, COSV52201989; called by muse, mutect2, varscan2
- ITIH2 | c.1357A>T p.M453L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100623458; called by muse, mutect2, varscan2
- IWS1 | c.2000A>T p.H667L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV99767567; called by muse, mutect2, varscan2
- KDM2A | c.3079G>C p.A1027P | Missense Mutation (SNP) | VAF 82/101 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100445859; called by muse, mutect2, varscan2
- KIAA2026 | c.4975A>T p.N1659Y | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs201677434, COSV101199225; called by muse, mutect2, varscan2
- KMT2D | c.15568C>T p.Q5190* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99986284; called by muse, mutect2, varscan2
- KRT81 | c.1178T>G p.M393R | Missense Mutation (SNP) | VAF 89/160 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100577030; called by muse, mutect2, varscan2
- LCN2 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 133/159 reads (84%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760072981, COSV52980820; called by muse, mutect2, varscan2
- LGI2 | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101180952; called by muse, mutect2, varscan2
- LRRC37A3 | c.637G>C p.V213L | Missense Mutation (SNP) | VAF 98/349 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.526); catalogued as COSV100141541; called by muse, varscan2
- MAGED2 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.638); catalogued as COSV99514790; called by muse, mutect2, varscan2
- MAN2A1 | c.577C>G p.Q193E | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99811999; called by muse, mutect2, varscan2
- MARCHF1 | c.794T>C p.V265A (on ENST00000274056; = p.V248A on NM_017923.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99922730; called by muse, mutect2, varscan2
- MORN3 | c.40T>C p.W14R | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100804518; called by muse, mutect2, varscan2
- MUC3A | c.9203C>T p.T3068I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV100115522; called by muse, mutect2, varscan2
- MYH1 | c.3325C>A p.Q1109K | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56845953; called by muse, mutect2, varscan2
- MYH13 | c.248C>G p.P83R | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52822437, COSV99355078, COSV99355676; called by muse, mutect2, varscan2
- MYH7 | c.653A>C p.D218A | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100806750; called by muse, mutect2, varscan2
- MYH9 | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99339934; called by muse, mutect2, varscan2
- MYO18B | c.5263C>T p.H1755Y | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs749900091, COSV100125399; called by muse, varscan2
- NAV3 | c.6612C>G p.N2204K (on ENST00000397909 / NM_001024383.2; = p.N2182K on NM_014903.6) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as COSV99896238; called by muse, mutect2, varscan2
- NCBP2L | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs764981347, COSV100966531; called by muse, mutect2, varscan2
- NDUFA8 | c.323A>T p.D108V | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101056889; called by muse, mutect2
- NEB | c.19158G>C p.E6386D | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs749320722, COSV99428514; called by muse, mutect2, varscan2
- NIBAN1 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as COSV100836651; called by muse, mutect2, varscan2
- NSD3 | c.717G>T p.R239S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV100388431, COSV100388967; called by muse, mutect2, varscan2
- OR5I1 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100041733; called by muse, mutect2, varscan2
- OXT | c.73T>G p.C25G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99459221; called by muse, mutect2
- PAMR1 | c.55A>C p.I19L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99553396; called by muse, mutect2, varscan2
- PARS2 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.059); catalogued as COSV100988344; called by muse, mutect2, varscan2
- PCDHGA11 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 110/139 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99548095; called by muse, mutect2, varscan2
- PCSK6 | c.2887C>G p.R963G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV100624534; called by muse, mutect2, varscan2
- PIWIL2 | c.1447C>G p.H483D | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs375237290; called by muse, mutect2, varscan2
- PLCB2 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99542743; called by muse, mutect2, varscan2
- PLCH1 | c.1259C>T p.S420F (on ENST00000340059 / NM_001130960.2; = p.S432F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV100398411; called by muse, mutect2, varscan2
- POLQ | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 115/269 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs761630032, COSV51761801; called by muse, mutect2, varscan2
- PRKAR2B | c.1153C>G p.L385V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55927875, COSV99708740; called by muse, mutect2, varscan2
- PRKCZ | c.1732T>A p.F578I | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100423205; called by muse, mutect2, varscan2
- PWWP2B | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.42); catalogued as rs1423079569, COSV100535954; called by muse, mutect2, varscan2
- RASGRP3 | c.1486A>C p.N496H (on ENST00000402538 / NM_001349975.2; = p.N495H on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101274913, COSV67825201; called by muse, mutect2, varscan2
- RASSF9 | c.783C>A p.S261R | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100771622, COSV63434136; called by muse, mutect2, varscan2
- RHD | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100155315; called by muse, mutect2, varscan2
- RPGRIP1 | c.1631T>C p.M544T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99252083; called by muse, mutect2, varscan2
- RTN4 | c.90G>T p.E30D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV100464070; called by muse, mutect2, varscan2
- RTTN | c.971G>T p.R324I | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99733966; called by muse, mutect2, varscan2
- SDC2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100144070; called by muse, mutect2, varscan2
- SIPA1L3 | c.956G>C p.G319A | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99730682; called by muse, varscan2
- SLAMF1 | c.336G>T p.K112N | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV99349662; called by muse, mutect2, varscan2
- SLC27A4 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM151697, COSV55959484; called by muse, mutect2, varscan2
- SLC5A10 | c.349-1G>C p.X117_splice | Splice Site (SNP) | VAF 85/114 reads (75%) | catalogued as COSV100525566; called by muse, mutect2, varscan2
- SLFN11 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 95/182 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV100391072; called by muse, mutect2, varscan2
- SMARCA5 | c.1759C>A p.L587I | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV51644879; called by muse, mutect2, varscan2
- SMG5 | c.2104T>G p.S702A | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100700940; called by muse, mutect2, varscan2
- SPANXN1 | c.19A>T p.S7C | Missense Mutation (SNP) | VAF 112/336 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100979450; called by muse, varscan2
- SSB | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99641931; called by muse, mutect2, varscan2
- STRN | c.1781G>T p.R594L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99815764; called by muse, mutect2, varscan2
- SYDE2 | c.3123A>T p.L1041F | Missense Mutation (SNP) | VAF 59/92 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.271); catalogued as COSV100416301; called by muse, mutect2, varscan2
- TAS2R38 | c.912G>C p.L304F | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV101516568; called by muse, mutect2, varscan2
- TBC1D16 | c.1392G>T p.E464D | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100188433; called by muse, mutect2, varscan2
- TCTN1 | c.822+1G>A p.X274_splice | Splice Site (SNP) | VAF 13/16 reads (81%) | catalogued as rs374065616; called by muse, varscan2
- TEX15 | c.923C>A p.T308K (on ENST00000256246; = p.T691K on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99822235; called by muse, mutect2, varscan2
- TLR4 | c.2340G>C p.R780S (on ENST00000355622 / NM_138554.5; = p.R740S on NM_003266.4) | Missense Mutation (SNP) | VAF 93/103 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100842886; called by muse, mutect2, varscan2
- TNRC6A | c.5542G>T p.A1848S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100170529; called by muse, mutect2, varscan2
- TNXB | c.7428G>C p.K2476N (on ENST00000647633; = p.K2229N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV64485226; called by muse, mutect2, varscan2
- TOP1 | c.1697A>G p.D566G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV100793976; called by muse, mutect2, varscan2
- TPR | c.6508G>A p.E2170K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100824274; called by muse, mutect2, varscan2
- TRPV3 | c.2202C>G p.I734M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100028222; called by muse, mutect2, varscan2
- TTN | c.45750G>T p.M15250I (on ENST00000591111; = p.M7826I on NM_003319.4) | Missense Mutation (SNP) | VAF 37/236 reads (16%) | PolyPhen benign (0.121); catalogued as rs767149312, COSV100632798; called by muse, mutect2, varscan2
- USH2A | c.12618G>T p.Q4206H | Missense Mutation (SNP) | VAF 86/137 reads (63%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as COSV100243320, COSV56331633; called by muse, mutect2, varscan2
- USP32 | c.3567C>A p.F1189L | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100342987; called by muse, mutect2, varscan2
- VPS4A | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54751149, COSV99652163; called by muse, mutect2, varscan2
- VPS52 | c.1449C>G p.I483M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV71403698; called by muse, mutect2, varscan2
- WDFY3 | c.3392C>T p.S1131F | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV55713338, COSV99885949; called by muse, mutect2, varscan2
- ZFX | c.1944G>C p.L648F | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100458179; called by muse, mutect2, varscan2
- ZNF140 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs980643258, COSV100166884; called by muse, mutect2
- ZNF593 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 48/60 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV99583505; called by muse, mutect2, varscan2
- ZNF780B | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1296833616, COSV99666201; called by muse, mutect2, varscan2
- ZWINT | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV100571579; called by muse, mutect2, varscan2
- CFAP70 | c.2741_2753del p.R914Mfs*44 | Frame Shift Del (DEL) | VAF 37/227 reads (16%) | called by mutect2, pindel, varscan2
- HCK | c.1048_1052del p.G350Qfs*9 | Frame Shift Del (DEL) | VAF 50/140 reads (36%) | called by mutect2, pindel, varscan2
- HIF1A | c.1456_1473del p.E486_M491del | In Frame Del (DEL) | VAF 52/205 reads (25%) | called by mutect2, pindel, varscan2
- LAMP2 | c.184-18_196del p.X62_splice | Splice Site (DEL) | VAF 34/114 reads (30%) | called by mutect2, pindel
- LILRB5 | c.1159_1165del p.S387Rfs*73 (on ENST00000449561 / NM_001081442.3; = p.S387Rfs*72 on NM_006840.5) | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- OR1S1 | c.388del p.T130Pfs*14 | Frame Shift Del (DEL) | VAF 74/131 reads (56%) | called by mutect2, pindel, varscan2
- PKHD1 | c.10053dup p.Y3352Ifs*22 | Frame Shift Ins (INS) | VAF 52/84 reads (62%) | called by mutect2, pindel, varscan2
- PTK2B | c.2507_2523+4del p.X836_splice | Splice Site (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- RPL23A | c.92_114del p.G31Efs*34 | Frame Shift Del (DEL) | VAF 16/168 reads (10%) | called by mutect2, pindel
- TAOK3 | c.1963_1972del p.T656* | Frame Shift Del (DEL) | VAF 67/85 reads (79%) | called by mutect2, pindel, varscan2
- TTF1 | c.210_220del p.R71* | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | called by mutect2, pindel*, varscan2*
- TTN | c.47652_47660del p.N15884_L15886del (on ENST00000591111; = p.N8460_L8462del on NM_003319.4) | In Frame Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- ZNF2 | c.-6_10del | Translation Start Site (DEL) | VAF 65/303 reads (21%) | called by mutect2, pindel, varscan2
- AGBL1 | c.2904G>A p.T968= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as rs372153251; called by muse, varscan2
- ATP13A3 | c.3642G>A p.K1214= (on ENST00000645319 / NM_001367549.1; = p.K1184= on NM_024524.3) | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV99757709; called by muse, mutect2, varscan2
- BRD3 | c.1299G>C p.V433= | Silent (SNP) | VAF 44/56 reads (79%) | catalogued as rs749998227, COSV100325597; called by muse, mutect2, varscan2
- CAB39L | c.612A>G p.Q204= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV100759659; called by muse, mutect2, varscan2
- CNTNAP4 | c.1251G>T p.G417= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV100273576; called by muse, mutect2, varscan2
- CNTNAP4 | c.2544A>C p.T848= | Silent (SNP) | VAF 110/143 reads (77%) | catalogued as rs1014143272, COSV100273578; called by muse, mutect2, varscan2
- DHX57 | c.3987T>A p.G1329= | Silent (SNP) | VAF 66/106 reads (62%) | catalogued as COSV99770001; called by muse, mutect2, varscan2
- DHX9 | c.12T>G p.V4= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100841541; called by muse, mutect2
- EZH1 | c.969T>C p.N323= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV101331458; called by muse, mutect2, varscan2
- FGA | c.1467T>C p.S489= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV100120788; called by muse, mutect2, varscan2
- GNB3 | c.231G>A p.G77= | Silent (SNP) | VAF 34/231 reads (15%) | catalogued as COSV99301742; called by muse, mutect2, varscan2
- GPR6 | c.333A>T p.V111= | Silent (SNP) | VAF 88/123 reads (72%) | catalogued as COSV99254602; called by muse, mutect2, varscan2
- GPR84 | c.408G>A p.G136= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs149258778, COSV57210569; called by muse, mutect2, varscan2
- GRM8 | c.1536G>A p.P512= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs774632571, COSV58809093, COSV58817276, COSV58852761; called by muse, mutect2, varscan2
- GUCY2F | c.2838C>G p.G946= | Silent (SNP) | VAF 34/206 reads (17%) | catalogued as COSV99484738, COSV99485756; called by muse, mutect2, varscan2
- IGKV1D-42 | c.42G>C p.L14= | Silent (SNP) | VAF 90/183 reads (49%) | called by muse, mutect2, varscan2
- IGLV5-52 | c.306C>T p.I102= | Silent (SNP) | VAF 110/273 reads (40%) | catalogued as rs1569066363; called by muse, mutect2, varscan2
- ILVBL | c.354G>A p.A118= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs1057122677, COSV54622188; called by muse, mutect2, varscan2
- KRT81 | c.870G>A p.R290= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100577031; called by muse, mutect2, varscan2
- LRRC45 | c.1986C>T p.P662= | Silent (SNP) | VAF 28/33 reads (85%) | catalogued as rs754733477, COSV100141976; called by muse, mutect2, varscan2
- MICALL1 | c.2061G>A p.E687= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV99317606; called by muse, mutect2, varscan2
- MTUS2 | c.1026C>A p.A342= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV101462386; called by muse, mutect2, varscan2
- MYO9A | c.5226G>A p.V1742= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100614454; called by muse, mutect2, varscan2
- NGF | c.321C>T p.V107= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs202005277; called by muse, mutect2, varscan2
- NPAS2 | c.2028G>A p.L676= | Silent (SNP) | VAF 38/44 reads (86%) | catalogued as COSV100177094; called by muse, mutect2, varscan2
- NR4A2 | c.1227C>G p.L409= | Silent (SNP) | VAF 45/235 reads (19%) | catalogued as COSV100277411; called by muse, mutect2, varscan2
- NYNRIN | c.2361T>C p.P787= | Silent (SNP) | VAF 67/141 reads (48%) | catalogued as rs755011424, COSV101230715; called by muse, mutect2, varscan2
- PCDHAC1 | c.303C>G p.L101= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV53840185; called by muse, mutect2, varscan2
- PCDHB16 | c.1878C>T p.T626= | Silent (SNP) | VAF 86/118 reads (73%) | catalogued as COSV99502981; called by muse, mutect2, varscan2
- PIK3C2B | c.2145C>T p.P715= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100916237; called by muse, mutect2, varscan2
- PKDREJ | c.4185A>T p.A1395= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV99479603; called by muse, mutect2, varscan2
- POM121L12 | c.504G>A p.E168= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs193120562, COSV101374958; called by muse, mutect2, varscan2
- PTPRS | c.4392G>A p.T1464= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs559581868, COSV53616158; called by muse, mutect2, varscan2
- RAD23B | c.78G>A p.L26= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100787770; called by muse, mutect2, varscan2
- SHISA2 | c.381C>A p.A127= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100096650; called by muse, mutect2
- SLC39A5 | c.1017C>T p.A339= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV99907696; called by muse, mutect2, varscan2
- SPEF2 | c.2229C>G p.G743= | Silent (SNP) | VAF 42/58 reads (72%) | catalogued as COSV100609033; called by muse, mutect2, varscan2
- STXBP5 | c.906G>C p.T302= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV51647444, COSV99471102; called by muse, mutect2, varscan2
- TAF1L | c.4662G>A p.K1554= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs1356135922, COSV54256762; called by muse, mutect2, varscan2
- TAF1L | c.3144G>A p.V1048= | Silent (SNP) | VAF 136/167 reads (81%) | catalogued as rs1053720519, COSV99645536; called by muse, mutect2, varscan2
- TMPRSS13 | c.639G>C p.G213= | Silent (SNP) | VAF 57/310 reads (18%) | catalogued as COSV101471508; called by muse, mutect2, varscan2
- TRO | c.1662C>A p.V554= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV99437410; called by muse, mutect2, varscan2
- VWF | c.5781C>T p.C1927= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV99780366; called by muse, mutect2, varscan2
- XXYLT1 | c.612C>T p.I204= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV59980706; called by muse, mutect2, varscan2
- ZNF518A | c.36A>G p.E12= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV100283772; called by muse, mutect2, varscan2
- AQP1 | c.*339C>T | 3'UTR (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100311061; called by muse, mutect2, varscan2
- LAYN | c.*2A>G | 3'UTR (SNP) | VAF 7/30 reads (23%) | catalogued as rs759317614, COSV100986285; called by muse, mutect2, varscan2
- MAGEA5 | n.143G>A | RNA (SNP) | VAF 117/193 reads (61%) | called by muse, mutect2, varscan2
- MIR129-1 | n.38C>A | RNA (SNP) | VAF 11/26 reads (42%) | called by muse, varscan2
- RBMX | c.109+75G>C | Intron (SNP) | VAF 15/142 reads (11%) | catalogued as COSV100284969; called by muse, mutect2, varscan2
- RPS2 | c.709+108T>C | Intron (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99238967; called by muse, mutect2, varscan2
- THRB | c.284-12836A>C | Intron (SNP) | VAF 57/78 reads (73%) | catalogued as COSV99769823; called by muse, mutect2, varscan2
